Somatic mutation profile of tumor specimen MMRF_2574_1_BM_CD138pos (aliquot MMRF_2574_1_BM_CD138pos_T1_KHS5U_L12882) from MMRF case MMRF_2574, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.5 years (27,213 days).
Specimen MMRF_2574_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbab618f-a069-4b96-aa03-0cf033d19a41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2574_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2574_1_PB_Whole_C3_KHS5U_L12881; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/502bb13e-84f5-49cb-8305-27c63b223c69

The open-access MAF lists 152 somatic variants for this specimen: 51 protein-altering or splice-affecting, 20 silent, 81 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 47, Missense Mutation 47, Silent 20, Intron 17, 5'UTR 6, 5'Flank 4, RNA 4, 3'Flank 3, Frame Shift Ins 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV99258299; called by muse, mutect2, varscan2
- ABCB11 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as rs868630930; called by muse, mutect2, varscan2
- ARAP3 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1385620143; called by muse, mutect2, varscan2
- ASMT | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV101172395; called by muse, mutect2
- BAIAP2 | c.1011C>A p.Y337* | Nonsense Mutation (SNP) | VAF 132/262 reads (50%) | catalogued as COSV58334540; called by muse, mutect2, varscan2
- CLUH | c.3163G>A p.G1055S (on ENST00000435359; = p.G1094S on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/87 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157108519; called by muse, mutect2, varscan2
- DDC | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV63566156; called by muse, mutect2, varscan2
- IGHJ4 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 14/66 reads (21%) | PolyPhen possibly damaging (0.795); catalogued as rs183645858; called by muse, mutect2
- MFSD6L | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 70/88 reads (80%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1040950680; called by muse, mutect2, varscan2
- NDOR1 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1177305953; called by muse, mutect2, varscan2
- RRP12 | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs948732852; called by muse, mutect2, varscan2
- TAAR1 | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 75/119 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1275786770; called by muse, mutect2, varscan2
- TMEM201 | c.169G>C p.V57L | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61050715; called by muse, mutect2, varscan2
- TMTC1 | c.2093G>A p.R698Q (on ENST00000539277 / NM_001193451.2; = p.R590Q on NM_175861.3) | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.63); catalogued as rs762814208, COSV55482562; called by muse, mutect2, varscan2
- TRIO | c.1520C>T p.S507L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs201650861; called by muse, mutect2, varscan2
- ZNF311 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as COSV101014303; called by muse, mutect2
- ZNF618 | c.1154C>T p.S385L (on ENST00000374126 / NM_001318042.2; = p.S292L on NM_133374.2) | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.996); catalogued as rs552764833, COSV55920430; called by muse, mutect2, varscan2
- ADGRB3 | c.3753G>T p.Q1251H | Missense Mutation (SNP) | VAF 107/235 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- AGTRAP | c.67T>A p.C23S | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CANX | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC144A | c.3078C>G p.S1026R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by mutect2, varscan2
- CLEC14A | c.1355T>C p.L452S | Missense Mutation (SNP) | VAF 200/384 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLOCK | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- COL20A1 | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CRACD | c.818A>G p.E273G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- CRHBP | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- DNAH9 | c.3395G>T p.G1132V | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- FAT4 | c.891A>T p.Q297H | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- FLNB | c.2789C>G p.P930R | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- GJA1 | c.683T>A p.L228H | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- LMNB1 | c.1450T>A p.Y484N | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MCCC2 | c.504C>G p.I168M | Missense Mutation (SNP) | VAF 90/182 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); called by muse, varscan2
- NLGN1 | c.2116C>T p.H706Y | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- NLRP10 | c.715dup p.R239Kfs*14 | Frame Shift Ins (INS) | VAF 36/94 reads (38%) | called by mutect2, varscan2
- NLRP10 | c.714delinsAA p.R239Kfs*14 | Frame Shift Ins (INS) | VAF 34/121 reads (28%) | called by mutect2*, pindel, varscan2*
- NRG2 | c.1225A>T p.I409F | Missense Mutation (SNP) | VAF 78/278 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NVL | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRKD1 | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- QRICH1 | c.594G>T p.Q198H | Missense Mutation (SNP) | VAF 91/193 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RBBP8 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 127/249 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RND3 | c.349-7T>G | Splice Region (SNP) | VAF 123/264 reads (47%) | called by mutect2, varscan2
- RNF111 | c.642G>C p.K214N | Missense Mutation (SNP) | VAF 84/335 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, varscan2
- RPEL1 | c.459G>C p.M153I | Missense Mutation (SNP) | VAF 95/200 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- SEMA4G | c.1706T>C p.L569P (on ENST00000370250; = p.L574P on NM_017893.3) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC36A4 | c.148C>G p.H50D | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- SMU1 | c.877A>T p.I293F | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- SPATA31D1 | c.2851A>G p.I951V | Missense Mutation (SNP) | VAF 88/203 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TPM4 | c.12C>G p.I4M | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- UBAP2L | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 128/564 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- USP15 | c.2204G>C p.R735T (on ENST00000280377 / NM_001351159.2; = p.R706T on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF616 | c.596G>T p.S199I | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.55); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- C6orf136 | c.276G>A p.E92= | Silent (SNP) | VAF 158/239 reads (66%) | called by muse, mutect2, varscan2
- CFHR1 | c.597T>G p.P199= | Silent (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2, varscan2
- DNAH9 | c.3102C>T p.I1034= | Silent (SNP) | VAF 73/124 reads (59%) | called by muse, mutect2, varscan2
- DNAJC6 | c.459G>T p.L153= | Silent (SNP) | VAF 55/108 reads (51%) | catalogued as COSV54782305; called by muse, mutect2, varscan2
- DSC2 | c.1761C>A p.P587= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as COSV51866903, COSV99199432; called by muse, mutect2, varscan2
- HDGFL1 | c.321G>A p.P107= | Silent (SNP) | VAF 68/139 reads (49%) | catalogued as rs1288711494, COSV57753233; called by muse, mutect2, varscan2
- IL24 | c.291G>A p.L97= | Silent (SNP) | VAF 76/213 reads (36%) | called by muse, mutect2, varscan2
- KCNE4 | c.237C>T p.G79= | Silent (SNP) | VAF 64/130 reads (49%) | catalogued as rs1351120746, COSV56054518; called by muse, mutect2
- LAMA5 | c.2496C>T p.D832= | Silent (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- OR2C3 | c.888G>A p.T296= | Silent (SNP) | VAF 76/157 reads (48%) | catalogued as rs1458387754, COSV100825798, COSV63575105; called by muse, mutect2, varscan2
- PCDHGB4 | c.1611G>A p.S537= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as rs751415442, COSV53947857; called by muse, mutect2, varscan2
- PNO1 | c.438G>A p.V146= | Silent (SNP) | VAF 108/384 reads (28%) | called by muse, mutect2, varscan2
- RECQL | c.738T>C p.P246= | Silent (SNP) | VAF 19/286 reads (7%) | called by muse, mutect2
- RERG | c.444T>C p.S148= | Silent (SNP) | VAF 44/82 reads (54%) | called by muse, mutect2
- SGCG | c.834T>C p.G278= | Silent (SNP) | VAF 23/23 reads (100%) | called by muse, mutect2, varscan2
- SIN3B | c.1968C>T p.Y656= | Silent (SNP) | VAF 37/143 reads (26%) | catalogued as rs747403136; called by muse, mutect2, varscan2
- SLC44A5 | c.492G>A p.L164= | Silent (SNP) | VAF 68/172 reads (40%) | called by muse, mutect2, varscan2
- TLCD2 | c.267C>T p.F89= | Silent (SNP) | VAF 61/84 reads (73%) | called by muse, mutect2, varscan2
- TRIM42 | c.843C>T p.S281= | Silent (SNP) | VAF 156/342 reads (46%) | catalogued as rs747463987; called by muse, mutect2, varscan2
- WDR7 | c.3213G>A p.A1071= | Silent (SNP) | VAF 64/122 reads (52%) | catalogued as rs769432844, COSV54353630; called by muse, mutect2, varscan2
- ADTRP | c.*545T>C | 3'UTR (SNP) | VAF 82/169 reads (49%) | called by muse, mutect2, varscan2
- ARHGDIA | c.*479C>T | 3'UTR (SNP) | VAF 11/81 reads (14%) | catalogued as rs1460703097; called by muse, mutect2, varscan2
- ARPC5 | c.-58G>A | 5'UTR (SNP) | VAF 118/718 reads (16%) | called by muse, mutect2, varscan2
- ATP10A | c.3166-60G>A | Intron (SNP) | VAF 8/105 reads (8%) | catalogued as rs574294574; called by muse, mutect2
- ATP5F1EP2 | n.103G>C | RNA (SNP) | VAF 82/83 reads (99%) | called by muse, mutect2, varscan2
- BCAS1 | chr20:53940064 C>T | 3'Flank (SNP) | VAF 61/147 reads (41%) | called by muse, mutect2
- C21orf91 | c.*4306A>G | 3'UTR (SNP) | VAF 19/107 reads (18%) | called by muse, mutect2, varscan2
- CACNG7 | chr19:53943493 del G | 3'Flank (DEL) | VAF 18/46 reads (39%) | catalogued as rs1240960488; called by mutect2, varscan2
- CAMK2N2 | c.*798C>G | 3'UTR (SNP) | VAF 74/164 reads (45%) | called by muse, mutect2, varscan2
- CHID1 | chr11:914445 G>A | 5'Flank (SNP) | VAF 35/67 reads (52%) | catalogued as rs755460157; called by muse, mutect2, varscan2
- CRLF3 | c.*17C>G | 3'UTR (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- CYBB | c.*2445G>C | 3'UTR (SNP) | VAF 36/36 reads (100%) | called by muse, mutect2, varscan2
- DACH2 | c.1751-1147T>C | Intron (SNP) | VAF 29/29 reads (100%) | called by muse, mutect2, varscan2
- DLC1 | c.*1962G>A | 3'UTR (SNP) | VAF 38/38 reads (100%) | called by muse, mutect2, varscan2
- EDNRB | c.*1296G>C | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- EMC7 | c.*197T>A | 3'UTR (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- ERBB4 | c.*3269G>T | 3'UTR (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- F8 | c.-20A>G | 5'UTR (SNP) | VAF 8/145 reads (6%) | called by muse, mutect2
- FADS1 | c.*609G>C | 3'UTR (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- FCAR | c.*231C>A | 3'UTR (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- FST | c.*783T>A | 3'UTR (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- GIGYF2 | c.2208+109T>A | Intron (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- GRM8 | c.1357+68096_1357+68119del | Intron (DEL) | VAF 22/206 reads (11%) | called by mutect2, pindel
- H1-10 | c.*214G>T | 3'UTR (SNP) | VAF 83/166 reads (50%) | called by muse, mutect2, varscan2
- HAVCR1 | c.*59C>T | 3'UTR (SNP) | VAF 49/640 reads (8%) | called by muse, mutect2
- HLX | c.*208C>G | 3'UTR (SNP) | VAF 59/97 reads (61%) | called by muse, mutect2, varscan2
- IL17RB | c.*96C>T | 3'UTR (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- IL1A | c.*382G>T | 3'UTR (SNP) | VAF 34/72 reads (47%) | catalogued as rs905645467; called by muse, mutect2, varscan2
- IPO13 | c.2398-173C>T | Intron (SNP) | VAF 64/136 reads (47%) | called by muse, mutect2, varscan2
- KCNJ6 | c.26-2097T>A | Intron (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- KIF13B | c.*164G>A | 3'UTR (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- KLKP1 | n.660C>T | RNA (SNP) | VAF 51/102 reads (50%) | called by muse, mutect2, varscan2
- LEPR | c.*4097C>T | 3'UTR (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- LINC00632 | n.104+2818T>G | Intron (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2, varscan2
- LRBA | c.7726+399A>G | Intron (SNP) | VAF 45/84 reads (54%) | called by muse, mutect2, varscan2
- LRRC47 | c.*457A>G | 3'UTR (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- LYPD6 | c.*3244A>G | 3'UTR (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- METTL4 | c.*1257T>A | 3'UTR (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- MIA2 | c.64-82C>T | Intron (SNP) | VAF 118/254 reads (46%) | called by muse, mutect2, varscan2
- MYH16 | n.2934G>A | RNA (SNP) | VAF 124/216 reads (57%) | catalogued as rs911896583; called by muse, mutect2, varscan2
- NIFK | c.*177T>C | 3'UTR (SNP) | VAF 53/108 reads (49%) | called by muse, mutect2
- NKX3-2 | c.*1029C>T | 3'UTR (SNP) | VAF 38/38 reads (100%) | called by muse, mutect2, varscan2
- NTRK3 | c.*9240G>A | 3'UTR (SNP) | VAF 129/188 reads (69%) | catalogued as rs1372916883; called by muse, mutect2, varscan2
- NUDT16 | c.*4781T>G | 3'UTR (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2
- OR51G2 | chr11:4915702 A>T | 5'Flank (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- OR7D1P | n.513C>T | RNA (SNP) | VAF 154/520 reads (30%) | called by muse, mutect2, varscan2
- PABPC4L | c.-133C>A | 5'UTR (SNP) | VAF 49/87 reads (56%) | called by muse, mutect2, varscan2
- PCDH15 | c.*1106_*1107del | 3'UTR (DEL) | VAF 11/30 reads (37%) | called by pindel, varscan2
- PGBD5 | chr1:230323214 C>T | 3'Flank (SNP) | VAF 11/303 reads (4%) | called by muse, mutect2
- PLPP2 | c.205-62G>A | Intron (SNP) | VAF 47/132 reads (36%) | catalogued as rs1182545568; called by muse, mutect2, varscan2
- PLXNA4 | c.*626T>C | 3'UTR (SNP) | VAF 56/123 reads (46%) | called by muse, mutect2, varscan2
- PPP1CB | chr2:28751748 G>A | 5'Flank (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- PRKAG3 | c.1168+14G>A | Intron (SNP) | VAF 22/36 reads (61%) | called by muse, mutect2, varscan2
- PTGER3 | c.*338_*339del | 3'UTR (DEL) | VAF 21/44 reads (48%) | called by mutect2, pindel, varscan2
- PTS | c.-9G>A | 5'UTR (SNP) | VAF 34/67 reads (51%) | catalogued as rs532103622; called by muse, mutect2, varscan2
- RNF125 | c.*2070A>G | 3'UTR (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- RPL28 | c.*1685C>T | 3'UTR (SNP) | VAF 90/196 reads (46%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.740+1807G>A | Intron (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.-86+4517C>G | Intron (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- SALL1 | c.*66T>A | 3'UTR (SNP) | VAF 63/151 reads (42%) | called by muse, mutect2, varscan2
- SELENON | c.*1918A>G | 3'UTR (SNP) | VAF 79/155 reads (51%) | called by muse, mutect2, varscan2
- SLC6A8 | c.*1026G>C | 3'UTR (SNP) | VAF 31/137 reads (23%) | called by muse, mutect2, varscan2
- SOX11 | c.*1659T>C | 3'UTR (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
- SPRY3 | c.*4823C>T | 3'UTR (SNP) | VAF 146/473 reads (31%) | catalogued as COSV57143836; called by muse, mutect2, varscan2
- ST7 | chr7:116953182 del AC | 5'Flank (DEL) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- SV2B | c.*823T>A | 3'UTR (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- SYT14 | c.1355-1256C>T | Intron (SNP) | VAF 51/278 reads (18%) | called by muse, mutect2, varscan2
- TENT5C | c.*196C>T | 3'UTR (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2
- TGOLN2 | c.*1749C>T | 3'UTR (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- TNS4 | c.*957C>T | 3'UTR (SNP) | VAF 12/25 reads (48%) | catalogued as rs984601388; called by muse, mutect2, varscan2
- TOMM70 | c.*1958C>T | 3'UTR (SNP) | VAF 43/120 reads (36%) | called by muse, mutect2, varscan2
- TRIM29 | c.1135-21G>A | Intron (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- TRPA1 | c.*1330A>T | 3'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- TUFT1 | c.*1779G>T | 3'UTR (SNP) | VAF 8/147 reads (5%) | called by muse, mutect2
- UFD1 | c.-79C>T | 5'UTR (SNP) | VAF 108/220 reads (49%) | called by muse, varscan2
- UNC13A | c.*705C>T | 3'UTR (SNP) | VAF 24/193 reads (12%) | called by muse, mutect2, varscan2
- UNC5C | c.*1555C>A | 3'UTR (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- WRAP53 | c.-1691G>C | 5'UTR (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- XKR6 | c.764+92145G>A | Intron (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- ZNF140 | c.10-170A>G | Intron (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- ZYG11B | c.*4288C>G | 3'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
